Somatic mutation profile of tumor specimen TCGA-AB-2919-03A (aliquot TCGA-AB-2919-03A-01W-0745-08) from TCGA case TCGA-AB-2919, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.0 years (19,724 days).
Specimen TCGA-AB-2919-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c3c7ce6-5442-47f9-8d32-aacc264a90bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2919-11A (Solid Tissue Normal), aliquot TCGA-AB-2919-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8bf0329-1cfe-40bf-88fb-718d313e7d7d

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 61/134 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 11/27 reads (41%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNMT3A | c.1490G>A p.C497Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779323387, COSV53043881; called by muse, mutect2, varscan2
- FGF21 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as rs746450614, COSV99711394; called by muse, mutect2
- GRIK2 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 62/329 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as rs267600750, COSV100026245, COSV59726325; called by muse, mutect2, varscan2
- IGLV3-27 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as rs550508994; called by muse, mutect2, varscan2
- PMS2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99763951; called by muse, mutect2, varscan2
- RBBP4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as rs766075227, COSV65132341; called by muse, mutect2, varscan2
- RIF1 | c.3432T>A p.H1144Q | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV54615065; called by muse, mutect2, varscan2
- UBP1 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 208/449 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52145090; called by muse, varscan2
- WT1 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 204/862 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs1554939072, CM156572, COSV60069719, COSV60069855, COSV60086929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR153 | c.243T>C p.G81= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100928470; called by muse, mutect2, varscan2
- MAP7D2 | c.1542G>A p.K514= | Silent (SNP) | VAF 134/326 reads (41%) | catalogued as COSV65526513; called by muse, mutect2, varscan2
- MPDZ | c.276G>A p.S92= | Silent (SNP) | VAF 113/253 reads (45%) | catalogued as rs964480360, COSV59938313; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYBPHL | c.669C>T p.N223= | Silent (SNP) | VAF 81/182 reads (45%) | catalogued as COSV64062380; called by muse, mutect2, varscan2
- NCAM1 | c.1374C>A p.S458= (on ENST00000316851 / NM_181351.5; = p.S448= on NM_000615.7) | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as COSV100377129; called by muse, mutect2
